Somatic mutation profile of tumor specimen TCGA-F4-6807-01A (aliquot TCGA-F4-6807-01A-11D-1835-10) from TCGA case TCGA-F4-6807, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.2 years (18,690 days).
Specimen TCGA-F4-6807-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23764cde-3a2e-4b34-8d81-3680fe0c2481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6807-10A (Blood Derived Normal), aliquot TCGA-F4-6807-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc383aaf-7a51-4438-947e-6f6591692c2a

The open-access MAF lists 176 somatic variants for this specimen: 135 protein-altering or splice-affecting, 40 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 40, Nonsense Mutation 9, Splice Site 3, In Frame Del 2, Splice Region 1, Frame Shift Del 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV52703732; called by muse, mutect2, varscan2
- ACTN3 | c.1853G>T p.W618L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100074211, COSV59750529; called by muse, mutect2, varscan2
- ACTRT1 | c.1123T>C p.C375R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947538; called by muse, mutect2, varscan2
- ADAM7 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV51534302; called by muse, mutect2, varscan2
- ADARB2 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746391870, COSV67213227; called by muse, mutect2, varscan2
- ADGRD1 | c.2312C>A p.T771N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as COSV55437381; called by muse, mutect2, varscan2
- ADGRL1 | c.991G>A p.V331M (on ENST00000340736 / NM_001008701.3; = p.V326M on NM_014921.5) | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61563413; called by muse, mutect2, varscan2
- AFF2 | c.3872C>A p.T1291N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53974411; called by muse, mutect2, varscan2
- ALDH1L1 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV56410034; called by muse, mutect2, varscan2
- APBB1IP | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV66130272; called by muse, mutect2, varscan2
- APOBR | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100112403, COSV60491876; called by muse, mutect2, varscan2
- ARHGAP35 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV68328901, COSV68333715; called by muse, mutect2, varscan2
- ARHGEF37 | c.842_849del p.L281Hfs*2 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | catalogued as COSV61367738; called by mutect2, pindel, varscan2
- ATRX | c.2435C>A p.S812Y | Missense Mutation (SNP) | VAF 125/307 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64870477; called by muse, mutect2, varscan2
- AURKC | c.893G>A p.R298Q (on ENST00000302804 / NM_001015878.2; = p.R264Q on NM_003160.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs575228273, COSV57140463; called by muse, mutect2, varscan2
- AWAT2 | c.890A>T p.Q297L | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV52142550; called by muse, mutect2, varscan2
- BTG4 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV63635052; called by muse, mutect2, varscan2
- C3 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs777574436, COSV55567866; called by muse, mutect2, varscan2
- C8B | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64776352; called by muse, mutect2, varscan2
- CA2 | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53405593; called by muse, mutect2, varscan2
- CAPN15 | c.2933T>C p.L978P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562320; called by muse, mutect2, varscan2
- CCDC51 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.017); catalogued as rs1302410935, COSV56486262; called by muse, mutect2, varscan2
- CCDC57 | c.1523A>T p.H508L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV58933820; called by muse, mutect2, varscan2
- CCDC74B | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750987487, COSV60100597; called by muse, mutect2, varscan2
- CENPE | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54375357, COSV54376474; called by muse, mutect2, varscan2
- CFAP58 | c.2120C>A p.P707H | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100866085; called by muse, mutect2, varscan2
- CIART | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV51742951; called by muse, mutect2, varscan2
- CNTN1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61635594, COSV61635910; called by muse, mutect2, varscan2
- COL12A1 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs779848906, COSV59388393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL24A1 | c.2792C>A p.P931Q | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV100993113; called by muse, mutect2, varscan2
- COL4A6 | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858251; called by muse, mutect2, varscan2
- CP | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs188639920, COSV52828776; called by muse, mutect2, varscan2
- CRISP1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs758435165, COSV59995595; called by muse, mutect2
- CSMD3 | c.9596G>T p.C3199F (on ENST00000297405 / NM_001363185.1; = p.C3030F on NM_052900.3) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830025; called by muse, mutect2, varscan2
- CUL1 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762885752, COSV57386318; called by muse, mutect2, varscan2
- CXorf58 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003041, COSV64857727; called by muse, mutect2, varscan2
- CYP27B1 | c.1046C>G p.A349G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56983634; called by muse, mutect2, varscan2
- DCAKD | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60201659; called by mutect2, varscan2
- DCLK1 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99710137; called by muse, mutect2
- DDR1 | c.1714G>T p.A572S (on ENST00000324771; = p.A535S on NM_001954.4) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61318445; called by muse, mutect2, varscan2
- DLG4 | c.310G>T p.A104S (on ENST00000399506 / NM_001321075.3; = p.A147S on NM_001365.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57236124; called by muse, mutect2, varscan2
- DMD | c.4141T>G p.L1381V | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100820323, COSV63732284; called by muse, mutect2
- DNAH5 | c.13448C>T p.T4483M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141828476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT3B | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52414545; called by muse, mutect2, varscan2
- EFEMP1 | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV100816779; called by muse, mutect2, varscan2
- ELF4 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV57451195; called by muse, mutect2, varscan2
- FBLN2 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as rs1476684290, COSV55480308; called by muse, mutect2, varscan2
- FIBCD1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53392304; called by muse, mutect2, varscan2
- FIP1L1 | c.1502A>C p.D501A | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV55781472; called by muse, mutect2, varscan2
- FLG2 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101165747; called by muse, mutect2
- FN1 | c.5792C>T p.T1931I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60545804; called by muse, mutect2, varscan2
- GAB4 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV101271933, COSV68753897; called by muse, mutect2, varscan2
- GAREM1 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52505275; called by muse, mutect2, varscan2
- GLI3 | c.3634G>A p.G1212S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV101229793; called by muse, mutect2, varscan2
- GLYR1 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.066); catalogued as rs760825256, COSV58925278; called by mutect2, varscan2
- GPATCH2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs200676995, COSV65132287; called by muse, mutect2, varscan2
- GRM7 | c.1448A>T p.Q483L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV63126892; called by muse, mutect2, varscan2
- HEPACAM | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV53428373; called by muse, mutect2, varscan2
- HNRNPDL | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as COSV99787049; called by muse, mutect2
- ILKAP | c.123A>T p.G41= | Splice Region (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99610934; called by muse, mutect2, varscan2
- ITGAM | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.18); catalogued as rs755777607, COSV54933096; called by muse, mutect2, varscan2
- KCNG1 | c.775-1G>A p.X259_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as COSV65367867; called by muse, mutect2, varscan2
- KCNH4 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs370501052; called by muse, mutect2, varscan2
- KCNMB2 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV64200349; called by muse, mutect2, varscan2
- KPNA1 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV60267481; called by muse, mutect2, varscan2
- LAP3 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56898101; called by muse, mutect2, varscan2
- LILRB3 | c.1883G>T p.G628V (on ENST00000346401; = p.G616V on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV54427538, COSV54432543; called by muse, mutect2, varscan2
- MAP10 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs371454812, COSV69362633; called by muse, mutect2, varscan2
- MAP3K7 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs762121500, COSV65223426; called by muse, mutect2, varscan2
- MOB3B | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV51774185; called by muse, mutect2, varscan2
- MPO | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51856423; called by muse, mutect2, varscan2
- MYOCD | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58496457; called by muse, mutect2, varscan2
- NPY2R | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.667); catalogued as COSV61527080; called by muse, mutect2, varscan2
- NPY2R | c.881A>C p.D294A | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100279578; called by muse, mutect2, varscan2
- NUP210 | c.5120C>A p.S1707Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.726); catalogued as COSV99595920; called by muse, mutect2, varscan2
- OCRL | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as CM055471, COSV63979992; called by muse, mutect2, varscan2
- OR2G6 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs757587119, COSV58573566; called by muse, mutect2, varscan2
- OR5T2 | c.336T>G p.Y112* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57587618; called by muse, mutect2, varscan2
- OR6C75 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.117); catalogued as rs199828790, COSV58551067; called by muse, mutect2, varscan2
- OTC | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50000009; called by muse, mutect2, varscan2
- PCARE | c.2770C>A p.L924M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.874); catalogued as COSV59052704; called by muse, mutect2, varscan2
- PCDHA3 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as rs782401655, COSV63538552; called by muse, mutect2, varscan2
- PCDHB3 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV50563867; called by muse, mutect2, varscan2
- PCYT2 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as rs374371929; called by muse, mutect2, varscan2
- PHOX2B | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV56929409; called by muse, mutect2, varscan2
- PID1 | c.603G>T p.E201D (on ENST00000354069 / NM_001330156.1; = p.E199D on NM_017933.5) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV62471902; called by muse, mutect2, varscan2
- PIK3C2B | c.3756C>A p.S1252R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV100916046; called by muse, mutect2, varscan2
- PLS1 | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV61832509; called by muse, mutect2, varscan2
- POU6F2 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV68866770, COSV68879870; called by muse, mutect2, varscan2
- PRKACG | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99598463; called by muse, mutect2, varscan2
- PXDNL | c.3334C>T p.R1112W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs757140816, COSV62476291; called by muse, mutect2
- PYGM | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99376915, COSV99377159; called by muse, mutect2, varscan2
- RABGAP1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58059447, COSV58060803; called by muse, mutect2, varscan2
- RASEF | c.2144A>C p.D715A | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100906828; called by muse, mutect2, varscan2
- SCN7A | c.4433G>C p.S1478T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); catalogued as COSV69267903; called by muse, mutect2, varscan2
- SFRP2 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56836588; called by muse, mutect2, varscan2
- SHANK1 | c.1687A>T p.K563* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99520706; called by muse, mutect2
- SLC12A5 | c.1957A>G p.K653E (on ENST00000454036 / NM_001134771.2; = p.K630E on NM_020708.5) | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54787010; called by muse, mutect2, varscan2
- SLC25A28 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65125143; called by muse, mutect2, varscan2
- SLCO1B1 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918230; called by muse, mutect2
- SLITRK3 | c.2098G>A p.G700S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.287); catalogued as rs200981800, COSV99578855; called by mutect2, varscan2
- SMTN | c.2344G>C p.G782R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as COSV100294194; called by muse, mutect2, varscan2
- SORCS1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53838147; called by muse, mutect2, varscan2
- SPG7 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51947266; called by muse, mutect2, varscan2
- SPPL2C | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as COSV100233988; called by muse, mutect2
- SPPL2C | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV61291609; called by muse, mutect2, varscan2
- SYT3 | c.749C>A p.P250Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV100143962; called by muse, mutect2, varscan2
- TBCK | c.1964C>A p.P655Q (on ENST00000273980 / NM_001163436.4; = p.P592Q on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56751571, COSV56757942; called by muse, mutect2, varscan2
- TET1 | c.2929C>T p.L977F | Missense Mutation (SNP) | VAF 95/169 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65381594; called by muse, mutect2, varscan2
- TFAP4 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52596655, COSV52596894; called by muse, mutect2, varscan2
- TLR3 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99710915; called by muse, mutect2, varscan2
- TMEM145 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1487451833, COSV100003730; called by muse, mutect2, varscan2
- TMEM61 | c.366-1G>A p.X122_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as rs761385381, COSV64873292; called by muse, mutect2, varscan2
- TNC | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762128715, COSV100405403; called by mutect2, varscan2
- TOGARAM2 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs760340544, COSV65419595; called by muse, mutect2, varscan2
- TRPC6 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60250536; called by muse, mutect2, varscan2
- TTC26 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58269122; called by muse, mutect2, varscan2
- TTN | c.5117A>T p.K1706M (on ENST00000591111; = p.K1660M on NM_003319.4) | Missense Mutation (SNP) | VAF 29/209 reads (14%) | PolyPhen probably damaging (0.988); catalogued as COSV59861227; called by muse, mutect2, varscan2
- UBA1 | c.1001A>T p.Q334L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60110895; called by muse, mutect2, varscan2
- UNC13A | c.2795G>T p.R932L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53186978, COSV53188783; called by muse, mutect2, varscan2
- UPRT | c.928T>A p.*310Kext*3 | Nonstop Mutation (SNP) | VAF 22/280 reads (8%) | catalogued as COSV100975804; called by muse, mutect2
- USH2A | c.12008A>T p.Q4003L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV56321579; called by muse, mutect2, varscan2
- VXN | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV59685103; called by muse, mutect2, varscan2
- XRN1 | c.2895G>C p.E965D | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs767968974, COSV53807260; called by muse, mutect2, varscan2
- ZBTB17 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV65267790; called by muse, mutect2, varscan2
- ZNF524 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.456); catalogued as rs141376459; called by muse, mutect2, varscan2
- ZNF804A | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100170994, COSV56433383; called by muse, mutect2, varscan2
- DNAH8 | c.542_544del p.R181_M182delinsL | In Frame Del (DEL) | VAF 41/163 reads (25%) | called by mutect2, pindel, varscan2
- GFPT2 | c.1580_1582del p.K527del | In Frame Del (DEL) | VAF 10/33 reads (30%) | called by pindel, varscan2
- IGHE | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- AGAP3 | c.2250G>T p.G750= (on ENST00000622464; = p.G786= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV68242973; called by muse, mutect2, varscan2
- APLNR | c.138C>T p.N46= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs138964036; called by muse, mutect2, varscan2
- C4orf50 | c.540G>A p.P180= (on ENST00000324058; = p.P1412= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs773895285, COSV60690192; called by muse, mutect2, varscan2
- CHRM3 | c.882A>G p.E294= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99697946; called by muse, mutect2, varscan2
- COL22A1 | c.3573A>T p.P1191= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100277426; called by muse, mutect2
- CPAMD8 | c.3900G>T p.V1300= (on ENST00000651564; = p.V1253= on NM_015692.5) | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV101488455; called by muse, mutect2, varscan2
- CSNK1G2 | c.411C>T p.F137= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as COSV55335775; called by muse, mutect2, varscan2
- CTSL | c.90C>A p.T30= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV58245555; called by muse, mutect2, varscan2
- CX3CR1 | c.927G>C p.G309= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV64192906, COSV64194532; called by muse, mutect2, varscan2
- DST | c.16266G>A p.S5422= (on ENST00000361203 / NM_001374722.1; = p.S3010= on NM_015548.5) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs369986184, COSV54995038, COSV55046248; called by muse, mutect2, varscan2
- EXOC3 | c.6G>A p.K2= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV59265467; called by muse, mutect2, varscan2
- FAT4 | c.12018G>A p.T4006= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs368157923; called by muse, mutect2, varscan2
- FUT1 | c.870G>A p.P290= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV59567232; called by muse, mutect2, varscan2
- GPBAR1 | c.774G>T p.G258= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV50306800; called by muse, mutect2, varscan2
- GSTM3 | c.87T>C p.D29= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99860183; called by muse, mutect2, varscan2
- IRF2BPL | c.1329G>A p.Q443= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV53145789; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.24C>T p.A8= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs373676102; called by muse, varscan2
- KAT6A | c.1572C>T p.S524= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55901891; called by muse, mutect2, varscan2
- KCNB2 | c.1449C>T p.D483= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs555669570, COSV73051774; called by muse, mutect2, varscan2
- MMP25 | c.489C>A p.P163= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV60678389; called by muse, mutect2, varscan2
- MYO9B | c.5811G>A p.K1937= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV55726566; called by muse, mutect2
- NCAM1 | c.2127C>T p.I709= (on ENST00000316851 / NM_181351.5; = p.I699= on NM_000615.7) | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV57509509; called by muse, mutect2, varscan2
- NOL9 | c.525T>C p.S175= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV60226572; called by muse, mutect2, varscan2
- OR4D11 | c.664C>T p.L222= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV57584456; called by muse, mutect2, varscan2
- PCDHA6 | c.807G>T p.R269= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as COSV65348888, COSV65359453; called by muse, mutect2, varscan2
- PIGV | c.276C>T p.P92= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as COSV50290310; called by muse, mutect2, varscan2
- PIPOX | c.543G>T p.G181= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV60140948; called by muse, mutect2, varscan2
- PRAMEF1 | c.648C>T p.S216= | Silent (SNP) | VAF 86/260 reads (33%) | catalogued as COSV60004898; called by muse, mutect2, varscan2
- RAB22A | c.456G>A p.A152= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs377712985; called by muse, mutect2, varscan2
- RAI2 | c.795C>A p.P265= | Silent (SNP) | VAF 57/121 reads (47%) | catalogued as COSV58962606; called by muse, mutect2, varscan2
- RIN3 | c.939C>A p.T313= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV53644390; called by muse, mutect2, varscan2
- RIPOR1 | c.1890C>A p.P630= (on ENST00000379312 / NM_001193522.2; = p.P626= on NM_024519.4) | Silent (SNP) | VAF 63/248 reads (25%) | catalogued as COSV50216902; called by muse, mutect2, varscan2
- RNF165 | c.243G>A p.S81= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs777077140, COSV53970672; called by muse, mutect2, varscan2
- SHROOM4 | c.2043A>G p.L681= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV56783418; called by muse, mutect2, varscan2
- SPPL2A | c.372A>G p.S124= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV55939600; called by muse, mutect2
- SYNE2 | c.14346T>C p.F4782= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100647239; called by muse, varscan2
- TF | c.1890C>T p.N630= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs754752269, COSV53917138; called by muse, mutect2, varscan2
- TFR2 | c.1719C>A p.S573= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV56152823; called by muse, mutect2, varscan2
- TSSK1B | c.264C>A p.I88= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101181023; called by muse, mutect2, varscan2
- ZXDC | c.1290C>T p.S430= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1392219469, COSV60445546; called by muse, mutect2, varscan2
- OFCC1 | n.309A>T | RNA (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
